Somatic mutation profile of tumor specimen BA2169D (aliquot aq-BA2169D) from BEATAML1.0 case 2399, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.7 years (14,152 days).
Specimen BA2169D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34adb9d0-5ddd-4ad3-9d10-567ae197ae63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2513D (Solid Tissue Normal), aliquot aq-BA2513D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59cc6279-2877-4ad8-ab2f-c521faec2091

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 87/328 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF10L | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1013769138, COSV51433455; called by muse, mutect2, varscan2
- COL19A1 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs183001892, COSV59579330; called by muse, mutect2, varscan2
- FAT2 | c.8584G>A p.E2862K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55825606; called by muse, mutect2, varscan2
- NBEAL2 | c.3868C>T p.R1290W | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1330626921, COSV52756771; called by muse, mutect2
- SACS | c.10720A>G p.N3574D | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1274951632; called by muse, mutect2, varscan2
- ARHGAP40 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, varscan2
- ITGB1BP2 | c.942G>C p.R314S | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB44 | c.1686+1G>C p.X562_splice | Splice Site (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- CFAP43 | c.3273G>A p.P1091= | Silent (SNP) | VAF 62/241 reads (26%) | catalogued as rs151017050; called by muse, mutect2, varscan2
- RAB11B | c.324G>A p.E108= | Silent (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- CILK1 | c.*50C>T | 3'UTR (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
